Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TS-01A (Primary Tumor).

Histopathology is characterized predominantly by features typical for diffuse astrocytoma. Focal increase in cellularity and detection of mitoses with proliferation index larger 8% argues for anaplasia.

Diagnosis

Anaplastic astrocytoma WHO grade III

OACF ICD-O-3
Astrocytoma, grade III
path 9401/3
Astrocytoma, anaplastic
9401/3
Site Brain, supratentorial NOS
C71.0
JW 7/25/13

Untranslated original report
is housed at the BCR

NIH/PA Discrepancy		✓

Source: NCI Genomic Data Commons file 1266e04b-58a8-447b-95f9-497cdfcb2d57 (TCGA-S9-A6TS.A6DF65CD-E78C-4CF8-ACC7-B35F2EF33ECA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).